Somatic mutation profile of tumor specimen 0DEV4A from CCDI case PBBPLF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.1 years (387 days).
Specimen 0DEV4A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6452d51e-082a-4567-a7fc-f58cbe5d2565.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV29 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57ba5e26-e755-4701-b6de-a1cef76e82d1

The open-access MAF lists 16 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 7, Missense Mutation 3, 5'UTR 2, RNA 2, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM133A | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 34/888 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59075717, COSV59075955; called by muse, mutect2
- FAM133A | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 34/877 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 32/1068 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- TAS1R3 | c.2394C>T p.L798= | Silent (SNP) | VAF 325/637 reads (51%) | catalogued as COSV100229696; called by muse, mutect2, varscan2
- CACNB4 | c.*95T>A | 3'UTR (SNP) | VAF 14/73 reads (19%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 14/141 reads (10%) | called by muse, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 24/186 reads (13%) | called by muse, varscan2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 24/176 reads (14%) | catalogued as rs768118261; called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, varscan2
- NRCAM | c.-57C>A | 5'UTR (SNP) | VAF 32/252 reads (13%) | catalogued as rs926414386, COSV100695372; called by muse, varscan2
- NRCAM | c.-58T>G | 5'UTR (SNP) | VAF 32/244 reads (13%) | called by muse, varscan2
- PSMA6 | c.171+99T>C | Intron (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- SENP6 | c.2288+11A>T | Intron (SNP) | VAF 22/560 reads (4%) | called by muse, mutect2
- SIMC1 | c.1677+98T>C | Intron (SNP) | VAF 9/84 reads (11%) | catalogued as COSV104418257; called by muse, varscan2
